Somatic mutation profile of tumor specimen C3N-00302-02 (aliquot CPT0008750012_1) from CPTAC case C3N-00302, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.0 years (21,532 days).
Specimen C3N-00302-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6eb42415-2b41-4910-8103-545078d9f179.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00302-31 (Blood Derived Normal), aliquot CPT0008790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93f5f43a-49b7-4cc5-bc7a-ed8c84500281

The open-access MAF lists 38 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 10, Frame Shift Del 4, Intron 3, 3'UTR 1, 5'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 129/572 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1018del p.M340Cfs*5 | Frame Shift Del (DEL) | VAF 113/469 reads (24%) | catalogued as rs1131691005, COSV53461649, COSV53588660; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APOB | c.4796G>A p.R1599H | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs746414462, COSV51927055; ClinVar: likely benign; called by muse, mutect2, varscan2
- C19orf57 | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 16/441 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs890488306; called by muse, mutect2
- COPG1 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 72/426 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.768); catalogued as rs367768969; called by muse, mutect2, varscan2
- IL20RB | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 48/680 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV100290891, COSV100291102; called by muse, mutect2
- IRS1 | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 211/966 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs747061950; called by muse, mutect2, varscan2
- KRTAP4-8 | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 138/497 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs753185136; called by muse, varscan2
- LTBP2 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 109/670 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753186679; called by muse, mutect2, varscan2
- LVRN | c.2756+2T>A p.X919_splice | Splice Site (SNP) | VAF 37/174 reads (21%) | catalogued as COSV100773325; called by muse, mutect2, varscan2
- OR5R1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 63/357 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771782696, COSV56571910; called by muse, mutect2
- OSR1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 149/680 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as rs1236849681; called by muse, mutect2, varscan2
- PCDHB5 | c.2266G>A p.G756R | Missense Mutation (SNP) | VAF 138/590 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as rs781995647, COSV50647659; called by muse, mutect2, varscan2
- PCDHGB3 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 63/529 reads (12%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.819); catalogued as rs1229622208; called by muse, mutect2, varscan2
- PPP1R16B | c.1630C>G p.P544A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55379747, COSV55380289; called by muse, mutect2
- TBX20 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1363662149; called by muse, mutect2
- MIDEAS | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 208/971 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- RB1 | c.1749del p.D584Ifs*27 | Frame Shift Del (DEL) | VAF 171/542 reads (32%) | called by mutect2, pindel, varscan2
- SCRN1 | c.887_893del p.G296Vfs*17 | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | called by mutect2, pindel
- TP53TG3D | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.567); called by mutect2, varscan2
- ZIM2 | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 14/437 reads (3%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF407 | c.691del p.H231Ifs*29 | Frame Shift Del (DEL) | VAF 71/342 reads (21%) | called by mutect2, pindel, varscan2
- CLIP3 | c.300C>T p.G100= | Silent (SNP) | VAF 9/174 reads (5%) | called by muse, mutect2
- CORO2B | c.252C>T p.C84= | Silent (SNP) | VAF 133/421 reads (32%) | catalogued as rs775653466, COSV99962893; called by muse, mutect2, varscan2
- HAO2 | c.1029A>T p.R343= | Silent (SNP) | VAF 101/456 reads (22%) | called by muse, mutect2, varscan2
- LAMC2 | c.1353C>T p.N451= | Silent (SNP) | VAF 116/709 reads (16%) | catalogued as rs141522697; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYF6 | c.264A>G p.K88= | Silent (SNP) | VAF 250/1102 reads (23%) | called by muse, mutect2, varscan2
- PATL2 | c.990C>T p.C330= | Silent (SNP) | VAF 72/271 reads (27%) | called by muse, mutect2, varscan2
- SATB1 | c.942T>A p.P314= | Silent (SNP) | VAF 77/444 reads (17%) | called by muse, mutect2, varscan2
- SOWAHA | c.912G>A p.A304= | Silent (SNP) | VAF 16/272 reads (6%) | called by muse, mutect2
- TMEM259 | c.180C>T p.F60= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- UBA3 | c.87G>T p.G29= | Silent (SNP) | VAF 83/361 reads (23%) | called by muse, mutect2, varscan2
- AK2 | c.*609G>C | 3'UTR (SNP) | VAF 38/478 reads (8%) | called by muse, mutect2
- COL1A2 | c.2349+24G>A | Intron (SNP) | VAF 109/723 reads (15%) | catalogued as rs762824227; called by muse, mutect2, varscan2
- CRB2 | c.3389+22G>A | Intron (SNP) | VAF 60/338 reads (18%) | catalogued as rs943584708; called by muse, mutect2, varscan2
- RAC1 | c.226-1414G>A | Intron (SNP) | VAF 57/342 reads (17%) | catalogued as rs148122613; called by muse, mutect2, varscan2
- REL | c.-93G>T | 5'UTR (SNP) | VAF 62/235 reads (26%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2689G>A | RNA (SNP) | VAF 118/663 reads (18%) | catalogued as rs760047563; called by muse, mutect2, varscan2
